Gene-level copy-number profile of tumor specimen HCM-SANG-0546-C15-08A-01D-A80T-32 from HCMI case HCM-SANG-0546-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0546-C15-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6c6832ee-fd9d-47d3-b428-3f4f075b6456.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0546-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/7668c056-69ba-430c-9b07-ea529070f14c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 9,982; copy number 2: 44,199; copy number 3: 3,070; copy number 4: 1,101; copy number 5: 161; copy number 6: 52; copy number 8: 147; copy number 10: 22; copy number 11: 12; copy number 18: 75; copy number 19: 38; copy number 20: 3; copy number 22: 16; copy number 38: 32.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:47,908,064–48,040,577, 6 genes: AC245041.2, NPY4R2, AC245041.1, FAM25C, AGAP12P, RNA5SP315.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 558 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:108,747,841–113,595,285, 70 genes, copy number 5–6 (broad region; genes not listed).
- chr6:33,620,365–36,024,868, 72 genes, copy number 6–10 (broad region; genes not listed).
- chr12:24,810,024–25,885,855, 28 genes, copy number 11–22: BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, AC019209.1.
- chr18:20,946,906–45,683,688, 310 genes, copy number 5–19 (within-gene range 1–19) (broad region; genes not listed).
- chr18:48,475,487–49,742,063, 35 genes, copy number 20–38: RNA5SP456, AC024288.1, POLR3GP2, CTIF, AC048380.2, AC048380.3, MIR4743, AC048380.1, AC022919.1, AC093567.1, SMAD7, AC114684.1, AC016866.3, AC016866.1, DYM, MIR4744, AC016866.2, AC044840.1, AC100778.1, AC100778.4, PRR13P4, C18orf32, RPL17-C18orf32, AC100778.2, AC100778.3, MIR1539, RPL17, SNORD58C, SNORD58A, SNORD58B, SRP72P1, LINC02837, LIPG, SMUG1P1, AC090227.3.
- chr20:57,895,394–59,460,837, 43 genes, copy number 5: AL162291.1, AL354984.1, LINC01742, AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2, PIEZO1P1.

Autosomal genes at a single copy (total copy number 1): 7,126. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
